Surgical pathology report (de-identified scan), TCGA case TCGA-DF-A2L0, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Ontario Institute for Cancer Research, specimen TCGA-DF-A2L0-01A (Primary Tumor).

Sample Type TUMOUR

Sample Preparation

Fresh Frozen

Site of Primary (Event)

Uterine

ICD-0-3

Site of Tissue

endometrial mass

adenocarcinoma, endometrioid, NOS

Year of Sample Collection

8380/3

Age at Sample Collection (yrs)

Sample Comments

Site: endometrium C 54.1

Days to Procedure Date

0

Days to Diagnosis

9

fw

Type of Procedure

Surgical resection

8/23/11

Site of Primary (Histology)

Endometrium

Bilateral Disease

UNK

Tumour Size (cm)

999.99000000000001

Histology

Endometrioid adenocarcinoma, NOS

Grade/Differentiation

III

Pathological T

T1c

Pathological N

N1

Number of Nodes Sampled

5

Number of Nodes Positive

17

Clinical M

M0

Histology Comments

Tumour size: Anterior 5.3 x 2.5 cm, 2.0 cm (thickness),

posterior 5.0 x 5.4 cm 3.2 cm (thickness).

Source: NCI Genomic Data Commons file e26c3f19-b526-4cf7-802b-91b8095bb434 (TCGA-DF-A2L0.1679CA2C-86BF-41D1-96E1-62FC89D9AAA7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).